Somatic mutation profile of tumor specimen MMRF_2814_1_BM_CD138pos (aliquot MMRF_2814_1_BM_CD138pos_T1_KHS5U_L15700) from MMRF case MMRF_2814, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2814_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb7087d0-f98b-4c8d-887e-1a77aa2947a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2814_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2814_1_PB_WBC_C3_KHS5U_L15746; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9462d9b5-be50-44ba-b9f3-51c05d8953df

The open-access MAF lists 127 somatic variants for this specimen: 48 protein-altering or splice-affecting, 15 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 45, Missense Mutation 43, Silent 15, Intron 14, Splice Site 2, 3'Flank 2, Splice Region 1, Frame Shift Del 1, 5'Flank 1, RNA 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 108/257 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- LRRC56 | c.326+1G>A p.X109_splice | Splice Site (SNP) | VAF 70/142 reads (49%) | catalogued as rs1564800859; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM28 | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.129); catalogued as COSV56103539; called by muse, mutect2, varscan2
- ADGRL3 | c.1621G>T p.A541S (on ENST00000506720 / NM_001322402.2; = p.A473S on NM_015236.6) | Missense Mutation (SNP) | VAF 129/247 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs535869784, COSV72229677; called by muse, mutect2, varscan2
- CDK8 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 108/138 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV67420900; called by muse, mutect2, varscan2
- IGHV4-34 | c.246C>G p.S82R | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs11546808; called by muse, varscan2
- ILF2 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV62628334; called by muse, mutect2, varscan2
- KIF5C | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs756117516, COSV101276165, COSV101276235; called by muse, mutect2, varscan2
- LCE2B | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs999874346, COSV100909310; called by muse, mutect2, varscan2
- NCAPD3 | c.2406G>T p.L802F | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200700272; called by muse, mutect2, varscan2
- PDE9A | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1216555374; called by muse, mutect2, varscan2
- POGZ | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs752798900; ClinVar: association / likely benign; called by muse, mutect2, varscan2
- UBE3A | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 81/94 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99217458; called by muse, mutect2, varscan2
- ZIC4 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101268161; called by muse, mutect2, varscan2
- ZNF626 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs1555769549; called by muse, mutect2, varscan2
- AHNAK | c.15001C>T p.P5001S | Missense Mutation (SNP) | VAF 122/299 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALS2CL | c.614A>C p.D205A | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ASCC3 | c.1856A>T p.D619V | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCDC158 | c.647del p.R216Pfs*11 | Frame Shift Del (DEL) | VAF 77/216 reads (36%) | called by mutect2, pindel, varscan2
- CPT1A | c.1468T>C p.S490P | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- DYSF | c.2626T>G p.S876A | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2
- EGR1 | c.238A>G p.S80G | Missense Mutation (SNP) | VAF 88/140 reads (63%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC5 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 126/264 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- FGFR1 | c.940G>A p.A314T (on ENST00000447712 / NM_023110.3; = p.A312T on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/273 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- HDC | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPG2 | c.1961C>A p.P654H | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP2K3 | c.499G>T p.G167W (on ENST00000342679 / NM_145109.3; = p.G138W on NM_002756.4) | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCRS1 | c.383T>A p.V128E | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- NBAS | c.4951C>G p.L1651V | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCSK6 | c.1895C>A p.T632K | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- PIP5K1A | c.1230-2A>T p.X410_splice (on ENST00000368888 / NM_001135638.2; = p.X397_splice on NM_003557.3) | Splice Site (SNP) | VAF 53/92 reads (58%) | called by muse, mutect2, varscan2
- POLR2A | c.4437G>T p.K1479N | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- RAPH1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RBM12B | c.78G>T p.L26F | Missense Mutation (SNP) | VAF 207/411 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA3A | c.517C>G p.P173A | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRGAP3 | c.426C>T p.S142= | Splice Region (SNP) | VAF 45/99 reads (45%) | called by muse, mutect2, varscan2
- STK32B | c.1190A>T p.D397V | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- STT3B | c.2473A>G p.T825A | Missense Mutation (SNP) | VAF 152/316 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TCEAL2 | c.200C>G p.A67G | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- TET1 | c.2433G>T p.M811I | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFR2 | c.1704C>A p.D568E | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TJP3 | c.1058C>A p.S353* | Nonsense Mutation (SNP) | VAF 92/259 reads (36%) | called by muse, mutect2, varscan2
- TMLHE | c.1142T>A p.F381Y | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TMPRSS11A | c.437A>T p.K146M | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TRAF3 | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRIL | c.1568C>A p.A523E | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM37 | c.2302G>T p.V768L | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC13A | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALDH16A1 | c.1494C>T p.S498= | Silent (SNP) | VAF 61/214 reads (29%) | called by muse, mutect2, varscan2
- CCDC42 | c.900G>A p.S300= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs781006395, COSV53449355, COSV53449740, COSV99549792; called by muse, mutect2, varscan2
- CHRNA4 | c.1683G>A p.S561= | Silent (SNP) | VAF 125/255 reads (49%) | catalogued as rs750265666, COSV100937339; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH5 | c.10681C>T p.L3561= | Silent (SNP) | VAF 91/208 reads (44%) | called by muse, mutect2, varscan2
- HSD17B7 | c.837C>G p.L279= | Silent (SNP) | VAF 54/133 reads (41%) | called by muse, mutect2
- HTR3D | c.675C>A p.R225= (on ENST00000382489 / NM_001163646.2; = p.R52= on NM_182537.3) | Silent (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- IGHV4-34 | c.87G>A p.Q29= | Silent (SNP) | VAF 78/90 reads (87%) | catalogued as rs11267027; called by muse, varscan2
- KITLG | c.474T>G p.S158= | Silent (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- LNPEP | c.2169G>A p.L723= | Silent (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- LRP2 | c.4755C>T p.D1585= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as rs141871628, COSV55546863; called by muse, mutect2, varscan2
- MAP3K3 | c.922C>T p.L308= | Silent (SNP) | VAF 150/231 reads (65%) | called by muse, varscan2
- NAV2 | c.7266C>T p.F2422= (on ENST00000396087 / NM_001244963.2; = p.F2363= on NM_145117.5) | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as rs1002131701; called by muse, mutect2, varscan2
- SHARPIN | c.786T>C p.G262= | Silent (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- TCF3 | c.777T>C p.S259= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as rs1184299722; called by muse, mutect2, varscan2
- ZNHIT2 | c.1009C>A p.R337= | Silent (SNP) | VAF 59/181 reads (33%) | called by muse, mutect2, varscan2
- ABAT | c.*1564G>T | 3'UTR (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- ABCC9 | chr12:21800874 C>A | 3'Flank (SNP) | VAF 13/42 reads (31%) | called by mutect2, varscan2
- AC023232.1 | n.265A>T | RNA (SNP) | VAF 69/93 reads (74%) | called by muse, mutect2, varscan2
- AFAP1 | c.*574G>C | 3'UTR (SNP) | VAF 55/133 reads (41%) | called by muse, mutect2, varscan2
- AMDHD2 | c.*745G>T | 3'UTR (SNP) | VAF 86/222 reads (39%) | called by muse, varscan2
- AMOTL1 | c.*5010G>A | 3'UTR (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- ARPC2 | c.268+502C>T | Intron (SNP) | VAF 87/214 reads (41%) | catalogued as rs1205961720; called by muse, mutect2, varscan2
- ATP13A5 | c.*202A>T | 3'UTR (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- CAAP1 | c.*1588T>C | 3'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- CBX6 | c.*4769G>A | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2
- CD99 | c.476-4756C>A | Intron (SNP) | VAF 97/104 reads (93%) | called by muse, mutect2, varscan2
- CFH | c.244+57A>T | Intron (SNP) | VAF 11/27 reads (41%) | called by mutect2, varscan2
- CSMD3 | c.178+59721G>T | Intron (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- DDX31 | c.903+433G>A | Intron (SNP) | VAF 49/113 reads (43%) | called by muse, mutect2, varscan2
- EDEM3 | c.*335A>T | 3'UTR (SNP) | VAF 51/99 reads (52%) | called by muse, mutect2, varscan2
- EGFR | c.1881-851_1881-850del | Intron (DEL) | VAF 64/187 reads (34%) | called by pindel, varscan2
- FBXO38 | c.*462C>T | 3'UTR (SNP) | VAF 66/143 reads (46%) | called by muse, mutect2
- GPR26 | c.*1136G>C | 3'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- GRIK1 | c.2694+59T>A | Intron (SNP) | VAF 159/323 reads (49%) | called by muse, mutect2, varscan2
- GRK2 | c.*569C>G | 3'UTR (SNP) | VAF 50/147 reads (34%) | called by muse, mutect2, varscan2
- GRM6 | c.*127C>T | 3'UTR (SNP) | VAF 14/28 reads (50%) | catalogued as rs879550882; called by muse, varscan2
- GTF3C4 | c.*2426C>A | 3'UTR (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- HSPB6 | c.*585C>T | 3'UTR (SNP) | VAF 50/158 reads (32%) | catalogued as rs762851078; called by muse, mutect2, varscan2
- IFNA17 | c.*207T>G | 3'UTR (SNP) | VAF 112/261 reads (43%) | called by muse, mutect2, varscan2
- IL13RA1 | c.1009+3393C>A | Intron (SNP) | VAF 109/345 reads (32%) | called by muse, mutect2, varscan2
- IL1A | c.*416G>T | 3'UTR (SNP) | VAF 46/87 reads (53%) | called by muse, mutect2, varscan2
- IPO11 | c.*938G>A | 3'UTR (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- IRF4 | c.*2233_*2277delinsAATTCTCCAAGCGGATGCTCCATTTCAATTGCTTTGTGA | 3'UTR (DEL) | VAF 14/47 reads (30%) | called by pindel, varscan2*
- JAG1 | c.-102G>A | 5'UTR (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- JCHAIN | c.*22T>G | 3'UTR (SNP) | VAF 150/321 reads (47%) | called by muse, mutect2, varscan2
- JOSD1 | c.*355C>T | 3'UTR (SNP) | VAF 44/76 reads (58%) | called by muse, mutect2, varscan2
- KIF3B | c.*2821C>A | 3'UTR (SNP) | VAF 114/247 reads (46%) | called by muse, mutect2, varscan2
- LBH | c.*2150C>A | 3'UTR (SNP) | VAF 44/89 reads (49%) | called by muse, mutect2, varscan2
- LCE2C | c.*130G>C | 3'UTR (SNP) | VAF 61/122 reads (50%) | called by muse, mutect2, varscan2
- LRRC14 | c.*2127C>A | 3'UTR (SNP) | VAF 107/235 reads (46%) | called by muse, mutect2, varscan2
- MAP3K3 | c.872-21C>G | Intron (SNP) | VAF 66/106 reads (62%) | called by muse, varscan2
- MAPK12 | c.1024+12G>T | Intron (SNP) | VAF 54/159 reads (34%) | called by muse, mutect2, varscan2
- MAPK14 | chr6:36027767 C>T | 5'Flank (SNP) | VAF 33/87 reads (38%) | catalogued as rs1051425625; called by muse, mutect2, varscan2
- MMP14 | c.*502C>A | 3'UTR (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- NTRK3 | c.*9277A>G | 3'UTR (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- OPRK1 | c.*1701T>C | 3'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- OSTM1 | c.*1787A>T | 3'UTR (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- PARVA | c.*1822G>T | 3'UTR (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- PDP1 | c.*1125T>A | 3'UTR (SNP) | VAF 47/82 reads (57%) | called by muse, mutect2, varscan2
- PTK2B | c.*468G>T | 3'UTR (SNP) | VAF 56/101 reads (55%) | called by muse, mutect2, varscan2
- PTRH2 | c.1-1789dup | Intron (INS) | VAF 14/132 reads (11%) | called by mutect2, pindel, varscan2
- PTTG1IP | c.*1289G>T | 3'UTR (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- RAB3B | c.*6129G>T | 3'UTR (SNP) | VAF 24/26 reads (92%) | called by muse, varscan2
- RNF103 | c.*310G>A | 3'UTR (SNP) | VAF 35/90 reads (39%) | catalogued as rs1020312608; called by muse, mutect2, varscan2
- RNF217 | c.*8799C>A | 3'UTR (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- SET | c.*1088C>T | 3'UTR (SNP) | VAF 134/415 reads (32%) | called by muse, mutect2, varscan2
- SLC12A1 | c.724+1181C>A | Intron (SNP) | VAF 60/166 reads (36%) | called by muse, mutect2
- SNTB2 | c.*1007G>T | 3'UTR (SNP) | VAF 49/58 reads (84%) | called by muse, mutect2, varscan2
- STX18 | chr4:4415990 C>T | 3'Flank (SNP) | VAF 80/207 reads (39%) | called by muse, mutect2, varscan2
- SYT8 | c.*75A>G | 3'UTR (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.*2336T>G | 3'UTR (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- TCHP | c.*161G>T | 3'UTR (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- TDRD9 | c.*440C>G | 3'UTR (SNP) | VAF 29/41 reads (71%) | called by muse, mutect2, varscan2
- TEAD1 | c.*6170G>T | 3'UTR (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- TMEM141 | c.54+39G>C | Intron (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- TRAK1 | c.1744+861G>A | Intron (SNP) | VAF 36/87 reads (41%) | catalogued as rs1012871870; called by muse, mutect2, varscan2
- ZNF211 | c.*576T>A | 3'UTR (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- ZNF621 | c.*1859G>A | 3'UTR (SNP) | VAF 57/117 reads (49%) | catalogued as rs973040446; called by muse, mutect2, varscan2
- ZNF844 | c.*89C>A | 3'UTR (SNP) | VAF 135/411 reads (33%) | called by muse, mutect2, varscan2
